Surgical pathology report (de-identified scan), TCGA case TCGA-QN-A5NN, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site ILSBio, specimen TCGA-QN-A5NN-01A (Primary Tumor).

[page 1 of 6]
Clinical Case Report

(For Collection of Cancerous Tissue)

ICD-O-3
Carcinoma
malignant mixed Mullerian
tumor 8950/3
Site: Endometrium C54.1
Jan 6/3/13

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight	☒ Single ☐ Married ☐ Divorced ☐ Widow	Vietnam	38°C
☐ Male ☒ Female			Blood Pressure	Heart Rate

HISTORY OF PRESENT ILLNESS	
Chief Complaints:	Vaginal bleeding post-menopausal
Symptoms:	Vaginal bleeding.
Clinical Findings:	- Normal vulva, blood in vaginal. - Normal cervix
Performance Scale (Karnofsky Score):	
☐ 100 Asymptomatic ☒ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden	

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
No				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 6]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status
normal			

OB/GYN HISTORY			
Menopausal Status	Date of First Menses	# of Pregnancies	
☐ Pre-menopausal		0	
☐ Peri-Menopausal	Date of Last Menses	# of Live Births	
☒ Post-menopausal		0	
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD		☐ Hormone Replacement Therapy: no	
☐ Other: none			

SOCIAL HISTORY				
Occupation: Retiree		Environmental Hazards: no		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis
normal		

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____	no	
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____	no	
Hep C	☐ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____	no	
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____	no	
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____	no	
B/T Cell Markers: no						

[page 3 of 6]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound	Mass in uterine cavity 10 x 18 mm	
X-Ray	normal	
CT	no	
Endoscopy	no	
MRI	no	
Biopsy	Endometrial carcinoma	

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Endometrial carcinoma.		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
cannot be assessed	cannot be assessed.	
Clinical Staging		Date of Diagnosis
T	N	M
Stage: T1a N0 M0		

Treatment Information = IA

SURGICAL TREATMENT			
Procedure			Date of Procedure
Radical hysterectomy; pelvic lymphadenectomy			
Primary Tumor			
Organ	Detailed Location	Size	
uteri	Mass in uterine cavity	4.5x 2 x 2 cm	
Extension of Tumor			
1/2 of myometrium.			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes	no	no	
Dissected Lymph Nodes	pelvic	6	
Distant Metastasis			
Organ	Detailed Location	Size	
no			
Surgical Staging			
T	N	M	Stage: T1b N0 M0 = I

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
no				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 6]
Pathology Form

Specimen Information

Collected by:

Date:

Time: _

Preserved by:

Date:

Time: _

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
3	1	3	1	1		3	1
Time to LN2		Time to Formalin		Time to LN2			
25 min		30 min		20 min			

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Colon	4.5 x 2 x 2 cm	1/3 of circumference	0.3 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Pelvic	6	NO	
Distant Metastasis			
Organ	Detailed Location	Size	
NA			
Pathological Staging			
pT	N	M	Stage: T1b N0 M0 cT3B
Notes:			

[page 5 of 6]
Microscopic Description

Histological Pattern											
Cell Distribution				Structural Pattern				Cellular Differentiation			
		+	-			+	-			+	-
Diffuse		+		Streaming		+					
Mosaic		+		Storiform							
Necrosis		+		Fibrosis		+					
Lymphocytic Infiltration			+	Palisading							
Vascular Invasion			+	Cystic Degeneration							
Clusterized		+		Bleeding		+					
Alveolar Formation		+		Myxoid Change							
Indian File			+	Psammoma/Calcification							

Cellular Differentiation											
Squamous		+	-	Adenomatous		+	-	Sarcomatous		+	-
Squamous Cell			+	Glandular cell		+		Round Cell		+	
Spindle Cell			+	Cell Stratification		+		Fibroblast		+	
Keratin			+	Secretion			+	Osteoblast			+
Desmosome			+	Intracyt. Vacuole			+	Lipoblast			+
Pearl			+	Gland formation			+	Myoblast			+

Cellular Differentiation:				Well	Moderate	Poor
----------------------------------	--	--	--	------	----------	------

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis			+	
Hyperchromatism			+	
Nucleolar Prominent			+	
Multinucleated Giant Cell	+			
Mitotic Activity		+		

Nuclear Grade:				
			+	

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive	no	
PR	☐ Negative ☐ Positive	no	
Her-2/neu	☐ Negative ☐ Positive	no	
B-Cell Marker	☐ Negative ☐ Positive	no	
T-Cell Marker	☐ Negative ☐ Positive	no	
Other:	☐ Negative ☐ Positive	no	
Other:	☐ Negative ☐ Positive	no	

Final Pathology Report

Histological Diagnosis: invasive carcinoma - carcinoma

Grade: II

Comments:

Principal Investigator

Pathologist

Date

[page 6 of 6]
Consolidated Pathology Diagnosis

ID#: _____

Histological Pattern											
Cell Distribution			+	-	Structural Pattern			+	-		
Diffuse						Streaming					
Mosaic						Storiform					
Necrosis						Fibrosis					
Lymphocytic Infiltration						Palisading					
Vascular Invasion						Cystic Degeneration					
Clusterized						Bleeding					
Alveolar Formation						Myxoid Change					
Indian File						Psammoma/Calcification					
Cellular Differentiation											
Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell			Round Cell			Large Cell		
Spindle Cell			Cell Stratification			Fibroblast			Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl			Gland formation			Myoblast			Plasma Cell		
Cellular Differentiation: ☐ Well ☐ Moderate ☒ Poor											
Nuclear Appearance											
Nuclear Atypia:				0	I	II	III				
Aniso Nucleosis											
Hyperchromatism											
Nucleolar Prominent											
Multinucleated Giant Cell											
Mitotic Activity											
Nuclear Grade:											

Final Pathology Report

Histological Diagnosis: Carcino-Sarcoma Grade: 3
(Malignant Mixed Tumor)

Comments:

D1 80% D2 90% D3 90% D4 90%

Date

Director, Research Pathology

INTEGRATED REPORT OF FINDINGS BY COLLABORATORS AND

PATHOLOGIST

Case Is (re)staged		

Source: NCI Genomic Data Commons file 96c79aa4-e308-4ff8-a399-4963fe00358f (TCGA-QN-A5NN.424FC113-5168-4051-A809-E244AB97FD72.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).